Somatic mutation profile of tumor specimen 0DFPU6 from CCDI case PBBSFL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astroblastoma; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 13.2 years (4,805 days).
Specimen 0DFPU6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5960b039-d447-4326-b1b1-f540fd898caf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFPU7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9762abec-9dc3-4891-ac64-294e8bb56772

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 3, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD16A | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 195/471 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs142905776; called by muse, mutect2, varscan2
- OR51S1 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 149/385 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs148053298; called by muse, mutect2, varscan2
- RBP1 | c.167G>A p.S56N (on ENST00000619087 / NM_001365940.2; = p.S118N on NM_002899.5) | Missense Mutation (SNP) | VAF 198/549 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- CDC5L | c.1482A>G p.L494= | Silent (SNP) | VAF 199/503 reads (40%) | catalogued as rs140651892; called by muse, mutect2, varscan2
- SPTBN5 | c.258C>T p.D86= | Silent (SNP) | VAF 34/844 reads (4%) | catalogued as rs751070750, COSV58020219; called by muse, mutect2
- WDFY4 | c.6174C>T p.S2058= | Silent (SNP) | VAF 179/470 reads (38%) | called by muse, mutect2, varscan2
